Gene-level copy-number profile of tumor specimen HCM-BROD-0001-C18-06A from HCMI case HCM-BROD-0001-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: GX; Age at diagnosis: 47.4 years (17,316 days).
Specimen HCM-BROD-0001-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0f7683ed-f9d7-4870-8639-374eb81b5f45.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0001-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/8ccbb06b-1885-41e0-9c91-2c24eb644367

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 6; copy number 2: 15; copy number 3: 3,482; copy number 4: 14,911; copy number 5: 21,207; copy number 6: 9,720; copy number 7: 4,442; copy number 8: 2,677; copy number 9: 557; copy number 10: 184; copy number 11: 181; copy number 12: 16; copy number 13: 14; copy number 14: 166; copy number 15: 451; copy number 16: 188; copy number 17: 12; copy number 18: 147; copy number 19: 11.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 1,045 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–268,655, 22 genes, copy number 12–18: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.2.
- chr6:56,431,950–56,954,649, 5 genes, copy number 13: RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P.
- chr6:57,114,894–58,438,364, 18 genes, copy number 11 (within-gene range 9–11): ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.
- chr6:62,547,427–66,728,904, 31 genes, copy number 11–12 (within-gene range 10–12): AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P.
- chr6:67,456,346–67,986,503, 6 genes, copy number 11 (within-gene range 9–11): AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3.
- chr6:68,040,290–68,093,001, 2 genes, copy number 11: AL646090.2, AL646090.1.
- chr6:68,627,879–68,635,161, 1 gene, copy number 11: AL391807.1.
- chr6:70,216,040–70,609,334, 9 genes, copy number 11: COL9A1, AL160262.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1.
- chr6:75,285,014–75,493,800, 5 genes, copy number 12 (within-gene range 10–12): TMEM30A-DT, FILIP1, HMGB1P39, AL445465.1, U3.
- chr6:76,446,988–76,593,821, 4 genes, copy number 11: RNU6-261P, LINC02540, RNU6-84P, AL591030.1.
- chr6:77,496,119–79,234,738, 9 genes, copy number 11 (within-gene range 9–11): RPS6P7, MEI4, AL121718.1, AL450327.1, IRAK1BP1, PHIP, AL356776.1, AL356776.2, HMGN3.
- chr6:79,326,568–79,354,713, 2 genes, copy number 12: AL355379.1, AL078601.1.
- chr6:79,631,329–79,833,386, 2 genes, copy number 11: SH3BGRL2, LINC01621.
- chr6:80,046,715–80,346,270, 4 genes, copy number 11: AL591135.2, AL591135.1, AK4P5, BCKDHB.
- chr6:170,736,173–170,737,777, 1 gene, copy number 14: AL731684.1.
- chr8:85,833,377–87,755,718, 26 genes, copy number 11: AC100801.1, LINC02849, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1, AF121898.1, VTA1P2, IARS2P1.
- chr8:89,585,872–108,083,642, 328 genes, copy number 14–16 (broad region; genes not listed).
- chr8:108,162,787–108,443,496, 1 gene, copy number 16 (within-gene range 7–16): EIF3E.
- chr8:108,378,831–145,066,685, 540 genes, copy number 15–19 (broad region; genes not listed).
- chr9:137,459,952–138,253,217, 20 genes, copy number 11: PNPLA7, MRPL41, DPH7, ZMYND19, ARRDC1, AL590627.2, ARRDC1-AS1, EHMT1, Metazoa_SRP, SETP5, AL590627.1, MIR602, AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr18:22,164,886–22,419,294, 9 genes, copy number 13: GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
